Somatic mutation profile of tumor specimen MP2PRT-PAVYZH-TMP1-A (aliquot MP2PRT-PAVYZH-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVYZH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (808 days).
Specimen MP2PRT-PAVYZH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d0dfd17-0463-4e5d-94ee-19e01082f72f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYZH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYZH-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55d160e8-4631-4d0e-b8ba-be550fa437b0

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB12 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 238/249 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV62857501; called by muse, mutect2, varscan2
- CHD6 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 89/94 reads (95%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs759159347, COSV58561023; called by muse, mutect2, varscan2
- EIF2AK4 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 196/385 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371395483; called by muse, mutect2, varscan2
- MKRN3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 232/516 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1291266443; called by muse, mutect2, varscan2
- CRMP1 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 201/447 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CSN2 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- EPB41L3 | c.2711A>G p.E904G | Missense Mutation (SNP) | VAF 30/435 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.423); called by muse, mutect2
- IBA57 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 282/654 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITGA8 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 52/479 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KRTAP5-6 | c.11G>C p.C4S | Missense Mutation (SNP) | VAF 191/399 reads (48%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN3 | c.350T>G p.F117C (on ENST00000557594 / NM_001272020.2; = p.F749C on NM_004796.6) | Missense Mutation (SNP) | VAF 207/458 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PPP1R26 | c.2538G>A p.A846= | Silent (SNP) | VAF 237/459 reads (52%) | catalogued as rs779123719; called by muse, mutect2, varscan2
- SCN9A | c.2628C>T p.I876= (on ENST00000303354; = p.I865= on NM_002977.3) | Silent (SNP) | VAF 209/467 reads (45%) | catalogued as rs772981944, COSV57615021; called by muse, mutect2, varscan2
- TNIK | c.2952G>T p.T984= | Silent (SNP) | VAF 131/295 reads (44%) | catalogued as COSV52673487; called by muse, mutect2, varscan2
- TRAV9-1 | c.105G>A p.G35= | Silent (SNP) | VAF 193/433 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.88341C>T p.F29447= (on ENST00000591111; = p.F22023= on NM_003319.4) | Silent (SNP) | VAF 221/473 reads (47%) | catalogued as rs751923958, COSV100600851; called by muse, mutect2, varscan2
- ZNF653 | c.780G>A p.P260= | Silent (SNP) | VAF 248/540 reads (46%) | catalogued as rs768620905; called by muse, varscan2
